Surgical pathology report (de-identified scan), TCGA case TCGA-29-1704, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1704-02A (Recurrent Tumor).

[REDACTED]
Surg Path

CLINICAL HISTORY:

Malignant neoplasm ovary

GROSS EXAMINATION:

A. "Pelvic tumor". Received unfixed and placed in formalin is a 4.3 x 3.3 x 1.4 cm aggregate of soft diffusely erythematous and partially cauterized tissue with a scant amount of adherent membranous tissue. Normal ovary is not grossly identified. Representative sections in blocks A1-3.

[REDACTED]
MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. TUMOR IN PELVIS (AT LEVEL OF VAGINAL CUFF BETWEEN BLADDER & RECTUM):
CONSISTENT WITH RECURRENT SEROUS ADENOCARCINOMA OF OVARIAN ORIGIN.

NOTE: The tumor has the appearance of a mullerian tumor with features in various areas of serous, endometrioid and focally transitional cell carcinoma. These features are all consistent with the known prior serous adenocarcinoma of the ovary resected in

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

ICB-0-3
Carcinoma, serous 8441/3
Site: ovary, NOS c56.9

hw
1/26/15

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 98981a8e-f53d-4ce9-825b-2542bac343c4 (TCGA-29-1704.4C689C80-12E5-4E40-8A12-910D07C8C084.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).